Somatic mutation profile of tumor specimen TCGA-AF-3400-01A (aliquot TCGA-AF-3400-01A-01D-1989-10) from TCGA case TCGA-AF-3400, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.3 years (19,826 days).
Specimen TCGA-AF-3400-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 758042de-f2d1-4bee-a5ec-2868fa79e5a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-3400-10A (Blood Derived Normal), aliquot TCGA-AF-3400-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df7b5232-aa71-48b2-a8a4-cc6de528c974

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1D | c.1082G>T p.W361L | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101062833; called by muse, mutect2, varscan2
- ASIC4 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV100761522; called by mutect2, varscan2
- COL28A1 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV101258238; called by muse, mutect2, varscan2
- FAU | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs372080439; called by muse, mutect2
- KIAA0930 | c.730C>T p.R244C (on ENST00000336156 / NM_001009880.2; = p.R249C on NM_015264.2) | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs773175119, COSV52663495; called by muse, mutect2, varscan2
- KRT82 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs779332186, COSV57787021; called by muse, mutect2, varscan2
- NPR1 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV100901937; called by muse, mutect2, varscan2
- PTPRT | c.3470G>A p.R1157H | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201275244, COSV61962377; called by muse, mutect2, varscan2
- RGS8 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 59/560 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs752892468, COSV51121600; called by muse, mutect2, varscan2
- RIBC2 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs1038395496, COSV61581984; called by muse, mutect2, varscan2
- SLC23A3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 21/187 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV99840749; called by muse, mutect2, varscan2
- UBE4B | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs772803836, COSV53528269; called by muse, mutect2, varscan2
- WDR62 | c.4379A>T p.Q1460L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99543010; called by muse, mutect2, varscan2
- GREB1 | c.5148C>T p.H1716= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs199908531, COSV99301989; called by muse, mutect2, varscan2
- HYAL3 | c.366C>A p.G122= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV99807373; called by muse, mutect2, varscan2
